Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XO, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XO-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: **Multiple organ resection – left breast and axillary tissue**

Unit in charge:

Physician in charge:

Material collected on: :

Material received on: :

Expected time of examination: **up to 8 working days**Clinical diagnosis: **Cancer of the left breast.** Status following mammotome biopsy.

ICB-0-3

Carcinoma, infiltrating lobular, nos 8520/3

Site: breast, nos C50.9

4/12/11

Examination performed on

Macroscopic description:

Left breast sized 22 x 18 x 6 cm removed with axillary tissue of 7 x 5 x 3 cm and a skin flap of 15 x 7 cm.

Tumour sized 2.2 x 1.5 x 1.3 cm found in the outer lower quadrant; placed 1.5 cm from the lower boundary, 2 cm from the base; and 1.5 cm from the skin.

Lymph nodes of up to 1.5 cm in length.

Microscopic description:

Carcinoma lobulare invasivum NHG 2 (3+2+1/ 0 mitoses /10 HPF, visual area of 0.55mm). Infiltratio carcinoma mamillae.

Lesion in situ of the type carcinoma lobulare (LCIS) – pagetoid spread.

Glandular tissue showing parenchyma atrophy

Axillary lymph nodes:

Metastases carcinomatosae in lymphonodo (No I / X)

Histopathological diagnosis:

Carcinoma lobulare invasivum et lobulare in situ mammae sinistae. Invasive lobular carcinoma and carcinoma in situ of the left breast

Metastases carcinomatosae in lymphonodo axillae (No I / X). Cancer metastases in axillary lymph nodes. (NHG2, pT2, pN1a)

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

Expression of Ki 67 proliferation antigen found in 5% of cell nuclei.

E-cadherin – negative reaction on neoplastic cells. Ck7+

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3ba1a9cb-fc43-4422-8038-a47f3069b098 (TCGA-D8-A1XO.9AAB53EC-89A0-4878-BB9D-D96BC56B54C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).